Somatic mutation profile of tumor specimen TCGA-AG-A008-01A (aliquot TCGA-AG-A008-01A-01D-A183-10) from TCGA case TCGA-AG-A008, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 50.4 years (18,416 days).
Specimen TCGA-AG-A008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aacf818f-3fbf-405d-a256-ec1799562124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A008-10A (Blood Derived Normal), aliquot TCGA-AG-A008-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/953116d5-365d-4cf9-8421-c871d4687036

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH7 | c.8665C>T p.R2889* | Nonsense Mutation (SNP) | VAF 216/470 reads (46%) | catalogued as rs1179296507, COSV100417331; called by muse, mutect2, varscan2
- GRIP1 | c.1801G>A p.V601I (on ENST00000359742 / NM_001379345.1; = p.V549I on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 195/472 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199936956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM10 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61311090; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 34/281 reads (12%) | catalogued as rs759904440; called by mutect2, varscan2
- SEC24B | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs765040358; called by muse, mutect2, varscan2
- TBC1D9B | c.2026C>T p.L676F | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs905517567; called by muse, mutect2, varscan2
- WSCD2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs763690309, COSV99774666; called by mutect2, varscan2
- ZIC4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs766045409, COSV67170511, COSV67172399; called by muse, mutect2, varscan2
- TBX20 | c.951C>T p.Y317= | Silent (SNP) | VAF 214/375 reads (57%) | catalogued as rs113335362; called by muse, mutect2, varscan2
